Somatic mutation profile of tumor specimen MP2PRT-PAVHDC-TMP1-A (aliquot MP2PRT-PAVHDC-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHDC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,875 days).
Specimen MP2PRT-PAVHDC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e118ab9-694d-4d54-b64f-6801a7106e29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHDC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHDC-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f426f259-353c-472a-9443-b281d6b7b4b6

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15640C>T p.R5214C | Missense Mutation (SNP) | VAF 29/511 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123728, CM114916, COSV56407525; ClinVar: pathogenic; called by muse, mutect2
- ADGRB3 | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53240244, COSV99484051; called by muse, mutect2
- FAT1 | c.4892C>T p.A1631V | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs751475602, COSV71674405; called by muse, mutect2
- HCK | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778488179; called by muse, mutect2, varscan2
- PROM2 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 88/476 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs759955085; called by muse, mutect2, varscan2
- SCYGR5 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 314/696 reads (45%) | catalogued as rs541472351; called by muse, mutect2, varscan2
- CAPNS2 | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 155/350 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- SCN3A | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4F | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 192/424 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS2R41 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 150/343 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XPNPEP2 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 279/901 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ZNF131 | c.1535A>C p.H512P (on ENST00000509156 / NM_001330707.2; = p.H478P on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- ADGRV1 | c.786C>T p.P262= | Silent (SNP) | VAF 104/248 reads (42%) | catalogued as rs143841024, COSV67988410; called by muse, mutect2, varscan2
- FTHL17 | c.366C>T p.A122= | Silent (SNP) | VAF 288/944 reads (31%) | catalogued as rs769606455; called by muse, varscan2
- GRK1 | c.948C>T p.R316= | Silent (SNP) | VAF 173/376 reads (46%) | catalogued as rs563850908; called by muse, mutect2, varscan2
- NCOA6 | c.1833C>T p.G611= | Silent (SNP) | VAF 54/409 reads (13%) | called by muse, mutect2, varscan2
- NLRC3 | c.3051C>T p.D1017= | Silent (SNP) | VAF 36/320 reads (11%) | catalogued as rs369978468; called by muse, varscan2
- TINCR | c.45C>T p.H15= | Silent (SNP) | VAF 22/587 reads (4%) | called by muse, mutect2
- OTX2 | c.98-15C>T | Intron (SNP) | VAF 83/549 reads (15%) | called by muse, mutect2, varscan2
